Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0YK, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0YK-01A (Primary Tumor).

[page 1 of 3]
Chief of Pathology

Phone

Fax

Specimen:

Received:

Status:

Req#:

Spec Type: SURGICAL P

Subm Dr:

PREOPERATIVE DIAGNOSIS

LEFT BREAST CANCER INVASIVE

OPERATION PERFORMED

DATE:

DOCTOR(S):

PROCEDURE: SIMPLE MASTECTOMY/BX. EXCISIONAL SENTINEL NODE

TISSUE REMOVED

- A. LT MASTECTOMY
- B. RT MASTECTOMY
- C. LT SENTINEL NODE #1
- D. LT SENTINEL NODE #2

GROSS DESCRIPTION

PART A RECEIVED LABELED [REDACTED] LEFT MASTECTOMY STITCH AT 12 O'CLOCK, IS A SIMPLE MASTECTOMY SPECIMEN MEASURING 15 X 15 X 3.5 CM IN GREATEST DIMENSIONS. THE NIPPLE IS IN THE INFERIOR PORTION OF A SKIN ELLIPSE MEASURING 9.7 X 5.5 CM IN GREATEST DIMENSIONS. A SUTURE DENOTES 12 O'CLOCK. BLUE DYE IS NOTED IN THE SUPERIOR PORTION OF THE SPECIMEN. THE SUPERFICIAL MARGIN IS MARKED IN BLUE INK, THE DEEP MARGIN IN BLACK INK. SECTIONING REVEALS THE CENTRAL ASPECT OF THE BREAST TO CONSIST OF DENSE TAN FIBROUS TISSUE WITH FOCAL CYSTIC AREAS WITH BROWN MUCINOUS MATERIAL. THIS IS SURROUNDED BY BLAND YELLOW FATTY TISSUE AT THE PERIMETER. IN THE SUPERIOR 12 O'CLOCK AREA, THERE IS A DISTINCT PINK-TAN GRITTY AREA WITHIN THIS FIBROUS TISSUE WHICH MEASURES 1.6 X 1.3 X 3.5 CM, WHICH SPANS INTO THE 2 O'CLOCK AREA WHERE THERE IS FOCAL RED-TAN DISCOLORATION SUGGESTIVE OF PREVIOUS BIOPSY. GROSSLY, THESE AREAS OF FIRMNESS ARE CONTIGUOUS. THIS LESION IS 0.5 CM FROM THE DEEP MARGIN. A WING CLIP IS IDENTIFIED IN THIS 12 O'CLOCK AREA. SECTIONS ARE SUBMITTED AS FOLLOWS: A1--SKIN AND NIPPLE, A2 AND 3--12 O'CLOCK LESION WITH DEEP MARGIN (MIRROR IMAGE TO PROTOCOL), A4--TISSUE SUPERFICIAL TO LESION TO INCLUDE SUPERFICIAL MARGIN AND SKIN, A5--2 O'CLOCK AREA (MIRROR IMAGE TO PROTOCOL), A6--2 O'CLOCK AREA WITH DEEP MARGIN, A7--TISSUE SUPERFICIAL TO A8, A8--UPPER OUTER QUADRANT TISSUE BETWEEN THE 12:00 AND 2:00 AREAS (MIRROR IMAGE TO PROTOCOL), A9--UPPER INNER QUADRANT 2 CM FROM THE 12 O'CLOCK LESION, A10--LOWER INNER QUADRANT 3.5 CM FROM THE 12 O'CLOCK LESION, A11--LOWER OUTER QUADRANT 3.5 CM FROM THE 12 O'CLOCK LESION (NOTE: A9 THROUGH A10 ARE MIRROR IMAGES TO PROTOCOL SECTIONS), A12--TISSUE FROM CENTRAL BREAST, A13--ADDITIONAL TISSUE LOWER OUTER QUADRANT.

PART B RECEIVED LABELED [REDACTED] RIGHT MASTECTOMY STITCH AT 12 O'CLOCK, IS A SIMPLE MASTECTOMY SPECIMEN WITH OVERALL DIMENSIONS OF 20 X 16.5 X 3.0 CM. THE NIPPLE IS UNREMARKABLE AND SITS WITHIN A 9 X 4.5 CM SKIN ELLIPSE. A SUTURE DENOTES 12 O'CLOCK. THE SUPERFICIAL ASPECT IS MARKED IN BLUE, THE DEEP MARGIN IN BLACK INK. SECTIONING REVEALS THE

[page 2 of 3]
Chief of Pathology

Phone

Fax

Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Rec#: [REDACTED]

Spec Type: SURGICAL P

Subm Dr:

GROSS DESCRIPTION

(Continued)

CENTRAL ASPECT OF THE BREAST TO CONSIST OF DENSE PINK-TAN FIBROUS TISSUE WITH FOCAL AREAS OF CYST FORMATION CONTAINING BROWN OILY MATERIAL. THIS IS SURROUNDED BY A PERIMETER OF BLAND YELLOW FATTY TISSUE. SECTIONS ARE SUBMITTED AS FOLLOWS: B1--NIPPLE, B2--CENTRAL DEEP MARGIN, B3 AND 4--UPPER INNER QUADRANT, B5 AND 6--UPPER OUTER QUADRANT, B7 AND 8--LOWER OUTER QUADRANT, B9 AND 10--LOWER INNER QUADRANT. NOTE THAT B1, B3, B5, B7 AND B9 ARE MIRROR IMAGES TO PROTOCOL PIECES.

PART C RECEIVED FRESH LABELED [REDACTED], LEFT SENTINEL NODE #1, IS AN OVOID PORTION OF BLUE-STAINED TISSUE AND YELLOW FAT MEASURING 2.1 X 1.7 X 1.0 CM. SECTIONING REVEALS A 1.0 CM IN DIAMETER GROSSLY UNREMARKABLE LYMPH NODE. ONE-HALF IS SUBMITTED PER PROTOCOL; THE REMAINDER IS SUBMITTED LABELED C.

PART D RECEIVED FRESH LABELED [REDACTED], LEFT SENTINEL NODE #2, IS AN OVOID PORTION OF YELLOW FATTY TISSUE MEASURING 2 X 1.2 X 0.5 CM. SECTIONING REVEALS A 0.6 CM IN DIAMETER GROSSLY UNREMARKABLE LYMPH NODE. THE TISSUE IS SUBMITTED ENTIRELY LABELED D.

PATH PROCEDURES

PROCEDURES:

88307/4, IMMUNOPEROXIDAS/2, A BLK/13, B BLK/10, CBX X3, DBX X3

FINAL DIAGNOSIS

PART A LEFT BREAST, SIMPLE MASTECTOMY:

1. MULTICENTRIC IN SITU AND INVASIVE LOBULAR CARCINOMA OF BREAST, NUCLEAR GRADE II WITH MODERATE MITOTIC INDEX, WITH TUMOR IDENTIFIED IN THE PREVIOUSLY BIOPSIED SITES AND ALSO IN RANDOM SECTIONS FROM THE LOWER INNER QUADRANT, CENTRAL BREAST AND NIPPLE SKIN.
2. THE TUMOR NODULES MEASURE IN SIZE FROM 2 MM TO 35 MM (GROSSLY). THE DEEP MARGIN IS FREE OF NEOPLASM.
3. LYMPHATIC INVASION IS NOT IDENTIFIED.
4. A SMALL INTRAMAMMARY LYMPH NODE (1) IS NEGATIVE FOR TUMOR (SLIDE A7).
5. FIBROCYSTIC DISEASE WITH DENSE FIBROSIS AND FIBROADENOMA.

PART B RIGHT BREAST, SIMPLE MASTECTOMY: PROLIFERATIVE FIBROCYSTIC DISEASE WITH DENSE FIBROSIS, SCLEROSING ADENOSIS, APOCRINE METAPLASIA, CYST FORMATION AND RADIAL SCAR FORMATION. MICROCALCIFICATIONS ARE PRESENT. ATYPIA OR MALIGNANCY IS NOT IDENTIFIED.

PART C LEFT SENTINEL NODE #1, BIOPSY: LYMPH NODE (1), NEGATIVE FOR

[page 3 of 3]
Chief of Pathology

Phone

Fax

Patient:

(Continued)

Specimen:

Received:

Status:

Req#:

Spec Type: SURGICAL P

Subm Dr:

FINAL DIAGNOSIS

(Continued)

TUMOR BY STEP SECTION AND CYTOKERATIN STAIN. A FOCUS OF PERINODAL FIBROSIS IS PRESENT WHICH MAY REPRESENT A PREVIOUS BIOPSY SITE.

PART D LEFT SENTINEL NODE #2, BIOPSY: LYMPH NODE (1), NEGATIVE FOR TUMOR BY STEP SECTION AND CYTOKERATIN STAIN.

Signed _____ (prelim.)

_____(signature on file)_____

Source: NCI Genomic Data Commons file 25580f58-a68c-4d21-8258-d4a9fdde33ea (TCGA-A2-A0YK.C3B5F075-864A-4D8B-B0CB-1B1FA28ACF4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).